Somatic mutation profile of tumor specimen C3L-00935-01 (aliquot CPT0027220009) from CPTAC case C3L-00935, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 74.8 years (27,315 days).
Specimen C3L-00935-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ee6a807-7d53-472c-9136-4693ecae6d5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00935-31 (Blood Derived Normal), aliquot CPT0027280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f442a757-bee0-4ada-a109-c0804a191b69

The open-access MAF lists 70 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Intron 3, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, 3'UTR 1, 5'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 221/241 reads (92%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS5 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.501); catalogued as rs367992476, COSV53177630; called by muse, mutect2, varscan2
- ANGPT4 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs370994711, COSV67920923; called by muse, mutect2, varscan2
- ASB15 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs764016921, COSV51926341; called by muse, mutect2, varscan2
- CDH10 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs773181787; called by muse, mutect2
- CHRDL2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.375); catalogued as rs536498622, COSV55225561; called by muse, mutect2, varscan2
- CNTNAP5 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs766550372, COSV70479048, COSV70493114; called by muse, mutect2, varscan2
- COL12A1 | c.7258G>T p.G2420C | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290886066; called by muse, mutect2, varscan2
- CRYBG3 | c.6509G>A p.R2170H | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761041275; called by muse, mutect2, varscan2
- CYSLTR1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377751262, COSV64820071; called by muse, mutect2
- DKC1 | c.1259+1G>T p.X420_splice | Splice Site (SNP) | VAF 12/123 reads (10%) | catalogued as CS083893; called by muse, mutect2, varscan2
- FBXW7 | c.1507G>A p.A503T (on ENST00000281708 / NM_001349798.2; = p.A423T on NM_018315.5) | Missense Mutation (SNP) | VAF 114/204 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55915797; called by muse, mutect2, varscan2
- FCHSD2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs1461032422; called by muse, mutect2, varscan2
- HNRNPH2 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57266629; called by muse, mutect2, varscan2
- LRFN2 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs749352903, COSV57826084; called by muse, mutect2, varscan2
- LRP2 | c.3738C>G p.N1246K | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1291722918; called by muse, mutect2, varscan2
- MRPL47 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.487); catalogued as rs1390922425; called by muse, mutect2, varscan2
- MYH2 | c.4339G>A p.A1447T | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs765747036, COSV99821319; called by muse, mutect2, varscan2
- PLCD4 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs759790901; called by muse, mutect2, varscan2
- PLEKHG6 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs757905511; called by muse, mutect2, varscan2
- PLXNB1 | c.1416C>G p.S472R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV56491674; called by muse, mutect2, varscan2
- PPP1R3A | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV52888137; called by muse, mutect2, varscan2
- PREX2 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as rs748595305, COSV55802043; called by muse, mutect2, varscan2
- SIGLEC10 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as rs756690528, COSV59485826; called by muse, mutect2, varscan2
- TBL3 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs1000429083; called by muse, mutect2, varscan2
- UGT2B11 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs754330334; called by muse, varscan2
- ZNF229 | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); catalogued as COSV52161812; called by muse, mutect2, varscan2
- ANKRD7 | c.13_20del p.F5Lfs*6 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- ATM | c.5478del p.L1826Ffs*2 | Frame Shift Del (DEL) | VAF 27/41 reads (66%) | called by mutect2, pindel, varscan2
- C7 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CD300LF | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL4A5 | c.2269G>C p.G757R | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELK4 | c.1235T>G p.L412R | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- GNPTG | c.30G>C p.L10F | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- IRS4 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 168/403 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT85 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 266/751 reads (35%) | called by muse, mutect2, varscan2
- KRT85 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRD1 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MARCHF1 | c.162+2T>C p.X54_splice | Splice Site (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- NSUN3 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.153); called by muse, mutect2
- PARP4 | c.2505G>T p.L835F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PIK3R5 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA4 | c.1668G>T p.K556N | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRICKLE3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- RAB39B | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SPTBN4 | c.6560G>A p.R2187H | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TERF2 | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 120/127 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TMEM35A | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF727 | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, varscan2
- ABLIM3 | c.957C>T p.Y319= | Silent (SNP) | VAF 70/142 reads (49%) | catalogued as rs537621133; called by muse, mutect2, varscan2
- CMBL | c.444C>T p.F148= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs146320422, COSV56983813; called by muse, varscan2
- GLS | c.1362A>C p.R454= | Silent (SNP) | VAF 66/161 reads (41%) | called by muse, mutect2, varscan2
- ITGAD | c.2670G>A p.R890= | Silent (SNP) | VAF 169/315 reads (54%) | called by muse, mutect2, varscan2
- LAMB3 | c.2254C>T p.L752= | Silent (SNP) | VAF 122/422 reads (29%) | called by muse, mutect2, varscan2
- LMO7 | c.4608G>T p.V1536= (on ENST00000357063; = p.V1217= on NM_005358.5) | Silent (SNP) | VAF 61/182 reads (34%) | called by muse, mutect2, varscan2
- MROH5 | c.1101G>A p.S367= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs571951791; called by muse, mutect2, varscan2
- PAPSS1 | c.1074G>A p.T358= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs368108957; called by mutect2, varscan2
- SCP2D1 | c.198C>T p.V66= | Silent (SNP) | VAF 72/228 reads (32%) | called by muse, mutect2, varscan2
- SLC9A5 | c.1635C>T p.H545= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as rs756494961; called by muse, mutect2, varscan2
- SORCS1 | c.1329A>G p.T443= | Silent (SNP) | VAF 37/225 reads (16%) | called by muse, mutect2, varscan2
- STAP2 | c.681C>T p.D227= | Silent (SNP) | VAF 143/157 reads (91%) | called by muse, mutect2, varscan2
- STAT1 | c.948G>A p.S316= | Silent (SNP) | VAF 78/311 reads (25%) | catalogued as rs759164014; called by muse, mutect2, varscan2
- USP34 | c.5820T>C p.L1940= | Silent (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- GUSBP10 | n.324C>A | RNA (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- HDAC4 | chr2:239401765 G>A | 5'Flank (SNP) | VAF 9/15 reads (60%) | catalogued as rs544322488; called by muse, mutect2
- PCDHA10 | c.2388+4494C>T | Intron (SNP) | VAF 242/398 reads (61%) | catalogued as COSV56531480; called by muse, mutect2, varscan2
- RNF181 | c.*33C>T | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- TK1 | c.-27C>G | 5'UTR (SNP) | VAF 66/312 reads (21%) | catalogued as COSV100015082; called by muse, mutect2, varscan2
- TMEM161B | c.914+24G>T | Intron (SNP) | VAF 46/200 reads (23%) | called by mutect2, varscan2
- ZGRF1 | c.2668-1503dup | Intron (INS) | VAF 11/17 reads (65%) | catalogued as rs765099386; called by mutect2, varscan2
